Gene-level copy-number profile of tumor specimen TCGA-CQ-5329-01A from TCGA case TCGA-CQ-5329, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.6 years (17,028 days).
Specimen TCGA-CQ-5329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0fd23c10-91cd-4ccb-a806-c5e6e9ee5c23.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-5329-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/745c8b97-6fba-430c-9008-a3ed5d1993b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,282; copy number 2: 35,472; copy number 3: 15,615; copy number 4: 5,011; copy number 5: 5; copy number 6: 17; copy number 11: 288; copy number 12: 125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-5329-01A-01D-1682-01): tumor purity 0.58, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 435 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:54,509,812–69,772,005, 310 genes, copy number 5–11 (broad region; genes not listed).
- chr14:74,084,796–77,935,014, 125 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
